Gene-level copy-number profile of tumor specimen TCGA-06-0211-02A from TCGA case TCGA-06-0211, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.0 years (17,515 days).
Specimen TCGA-06-0211-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.0c198e87-1f65-402a-bac6-b9b52c5bbd6d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0211-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90ea5c51-523c-478b-8fad-341ce20eb5a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 5,531; copy number 2: 46,747; copy number 3: 7,824; copy number 4: 3; copy number 6: 1; copy number 15: 17; copy number 17: 27; copy number 20: 16; copy number 28: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0211-02A-02D-2002-01): tumor purity 0.7, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–26,118,408, 84 genes (broad region; genes not listed).
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 79 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 6: CFHR3.
- chr4:53,377,839–54,295,272, 1 gene, copy number 15 (within-gene range 2–15): AC058822.1.
- chr4:53,899,871–54,607,131, 16 genes, copy number 15: AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260.
- chr7:54,185,071–55,955,239, 45 genes, copy number 17–28: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr7:55,951,877–55,956,500, 1 gene, copy number 17 (within-gene range 3–17): MRPS17.
- chr7:56,490,682–56,687,366, 15 genes, copy number 20: RBM22P3, AC092447.8, NMD3P2, AC092447.3, AC092447.5, VN1R25P, AC092447.2, AC092447.6, AC092447.1, AC092447.9, AC095038.5, TRIM60P16, AC095038.1, AC095038.4, AC095038.2.

Autosomal genes at a single copy (total copy number 1): 3,162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
